Gene-level copy-number profile of tumor specimen HTMCP-03-06-02414-01A from CGCI case HTMCP-03-06-02414, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02414-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 73498ed6-6053-4dfb-ace2-136b296f8155.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02414-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/542e42b7-2071-40d0-9dc5-2c08337b3883

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 56; copy number 2: 20,431; copy number 3: 30,874; copy number 4: 4,899; copy number 5: 1,960; copy number 6: 164; copy number 7: 13.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:56,991,888–57,020,273, 2 genes: TNRC18P3, SLC29A4P1.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:710,355–784,729, 2 genes, copy number 7: ZDHHC11B, BRD9P2.
- chr5:28,285,964–28,287,807, 1 gene, copy number 7: LINC02103.
- chr6:29,956,596–29,972,464, 2 genes, copy number 7: HLA-W, MICD.
- chr17:41,436,154–41,505,705, 8 genes, copy number 7: KRT38, KRT43P, KRT32, RNU2-32P, KRT35, KRT36, KRT13, AC019349.1.

Autosomal genes at a single copy (total copy number 1): 56. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
